Somatic mutation profile of tumor specimen C3L-01285-02 (aliquot CPT0087190009) from CPTAC case C3L-01285, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 54.0 years (19,737 days).
Specimen C3L-01285-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 66287b25-ae70-47ee-9556-c3510eb7bdee.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01285-31 (Blood Derived Normal), aliquot CPT0087480002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6d3e0588-66e9-4b1e-b860-5c65e150b053

The open-access MAF lists 336 somatic variants for this specimen: 236 protein-altering or splice-affecting, 62 silent, 38 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 199, Silent 62, Intron 20, Nonsense Mutation 14, Frame Shift Del 13, Splice Region 6, 5'UTR 6, 3'UTR 5, RNA 4, 5'Flank 2, In Frame Ins 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AGPS | c.1256G>A p.R419H | Missense Mutation (SNP) | VAF 168/388 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs121434411, CM983729; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KDM6A | c.1555C>T p.R519* | Nonsense Mutation (SNP) | VAF 79/103 reads (77%) | catalogued as rs397514628, CM1211999, COSV100938153, COSV65040077, COSV65043006; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.473G>C p.R158P | Missense Mutation (SNP) | VAF 203/418 reads (49%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs587782144, CM102353, CM165595, CM994513, COSV52676395, COSV52678258, COSV52680378, COSV53545833; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- TP53 | c.158G>A p.W53* | Nonsense Mutation (SNP) | VAF 164/374 reads (44%) | hotspot (GDC flag); catalogued as rs876658483, COSV52774899; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADAMTS1 | c.2520C>G p.Y840* | Nonsense Mutation (SNP) | VAF 66/202 reads (33%) | catalogued as COSV53171862; called by muse, mutect2, varscan2
- APBB1IP | c.249C>G p.I83M | Missense Mutation (SNP) | VAF 111/142 reads (78%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.757); catalogued as rs775214385; called by muse, mutect2, varscan2
- APOB | c.2570G>A p.G857E | Missense Mutation (SNP) | VAF 127/288 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1249889621; called by muse, mutect2, varscan2
- BCAT1 | c.28G>C p.A10P | Missense Mutation (SNP) | VAF 121/357 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV104369957; called by muse, mutect2, varscan2
- BCCIP | c.734C>T p.A245V | Missense Mutation (SNP) | VAF 57/158 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs199986344; called by muse, mutect2, varscan2
- CBX4 | c.518A>G p.Y173C | Missense Mutation (SNP) | VAF 135/325 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.788); catalogued as rs1281492719; called by muse, mutect2, varscan2
- CCDC172 | c.673C>T p.L225F | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT tolerated (0.36); PolyPhen benign (0.063); catalogued as rs1185577702; called by muse, mutect2, varscan2
- CCT7 | c.1132G>A p.A378T | Missense Mutation (SNP) | VAF 165/391 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.411); catalogued as rs1407228635, COSV54582507; called by muse, mutect2, varscan2
- CD83 | c.536G>T p.G179V | Missense Mutation (SNP) | VAF 48/173 reads (28%) | SIFT tolerated (0.59); PolyPhen benign (0.014); catalogued as rs1480726679; called by muse, mutect2, varscan2
- CELSR2 | c.3757G>A p.A1253T | Missense Mutation (SNP) | VAF 196/227 reads (86%) | SIFT deleterious (0.03); PolyPhen benign (0.359); catalogued as rs376393050; called by muse, mutect2, varscan2
- CISD1 | c.31G>T p.V11F | Missense Mutation (SNP) | VAF 34/77 reads (44%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.541); catalogued as COSV100445831; called by muse, mutect2, varscan2
- CLEC3A | c.532C>A p.L178M (on ENST00000651443; = p.L169M on NM_005752.6) | Missense Mutation (SNP) | VAF 62/338 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.125); catalogued as COSV55222222; called by muse, mutect2, varscan2
- CNTF | c.241C>T p.R81C | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs764894160; called by muse, mutect2, varscan2
- CNTN6 | c.2549C>A p.S850Y | Missense Mutation (SNP) | VAF 61/71 reads (86%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); catalogued as rs1037839968, COSV63179777, COSV63186987; called by muse, mutect2, varscan2
- COL15A1 | c.566G>T p.R189L | Missense Mutation (SNP) | VAF 128/164 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM142349; called by muse, mutect2, varscan2
- COL22A1 | c.3080G>T p.R1027L | Missense Mutation (SNP) | VAF 34/242 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.091); catalogued as COSV100279441; called by muse, mutect2, varscan2
- CPED1 | c.1934T>C p.F645S | Missense Mutation (SNP) | VAF 198/259 reads (76%) | SIFT deleterious (0); PolyPhen benign (0.022); catalogued as COSV104404430; called by muse, mutect2, varscan2
- CREBBP | c.6011G>A p.R2004Q | Missense Mutation (SNP) | VAF 45/144 reads (31%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.968); catalogued as rs1279369054, COSV99270488; called by muse, mutect2, varscan2
- CSMD3 | c.5294G>A p.R1765H (on ENST00000297405 / NM_001363185.1; = p.R1661H on NM_052900.3) | Missense Mutation (SNP) | VAF 131/391 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.052); catalogued as rs762865438, COSV52165347, COSV99844662; called by muse, mutect2, varscan2
- DACT1 | c.2173G>T p.E725* | Nonsense Mutation (SNP) | VAF 108/476 reads (23%) | catalogued as COSV60023097; called by muse, mutect2, varscan2
- DDX47 | c.905G>A p.R302H | Missense Mutation (SNP) | VAF 33/273 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761267089, COSV61911397; called by muse, mutect2, varscan2
- DNAH11 | c.8782G>T p.D2928Y | Missense Mutation (SNP) | VAF 89/154 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as rs768758217; called by muse, mutect2, varscan2
- DNAH9 | c.6356T>C p.I2119T | Missense Mutation (SNP) | VAF 77/164 reads (47%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs1475892904; called by muse, mutect2
- DNAJC13 | c.928G>T p.E310* | Nonsense Mutation (SNP) | VAF 53/183 reads (29%) | catalogued as COSV53449044; called by muse, mutect2, varscan2
- EIF3E | c.18G>C p.L6F | Missense Mutation (SNP) | VAF 78/226 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV55203932; called by muse, mutect2, varscan2
- FMN2 | c.4050G>T p.K1350N | Missense Mutation (SNP) | VAF 112/227 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100147813; called by muse, mutect2, varscan2
- FNDC1 | c.2311C>T p.L771F | Missense Mutation (SNP) | VAF 97/213 reads (46%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); catalogued as rs1215430860; called by muse, mutect2, varscan2
- FTMT | c.370G>C p.E124Q | Missense Mutation (SNP) | VAF 115/138 reads (83%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.517); catalogued as rs757322062, COSV58420540; called by muse, mutect2, varscan2
- GABRB3 | c.327C>A p.D109E | Missense Mutation (SNP) | VAF 66/188 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV54674991; called by muse, mutect2, varscan2
- GLI3 | c.827G>T p.S276I | Missense Mutation (SNP) | VAF 195/371 reads (53%) | SIFT tolerated (0.12); PolyPhen benign (0.147); catalogued as COSV67891944; called by muse, mutect2, varscan2
- GLTPD2 | c.415C>G p.R139G | Missense Mutation (SNP) | VAF 111/251 reads (44%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.463); catalogued as COSV100165305; called by muse, mutect2, varscan2
- GOLGA6L2 | c.976C>A p.Q326K | Missense Mutation (SNP) | VAF 91/123 reads (74%) | SIFT tolerated, low confidence (0.22); catalogued as rs570180093; called by muse, mutect2, varscan2
- GOLGA6L6 | c.1241G>T p.R414L | Missense Mutation (SNP) | VAF 76/182 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as COSV71180562; called by muse, mutect2, varscan2
- GOLGA8S | c.1648C>A p.P550T | Missense Mutation (SNP) | VAF 156/287 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1488049445; called by muse, varscan2
- HOXB3 | c.977C>T p.A326V | Missense Mutation (SNP) | VAF 26/47 reads (55%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.574); catalogued as COSV57488213; called by muse, mutect2, varscan2
- HS3ST5 | c.473C>A p.A158E | Missense Mutation (SNP) | VAF 56/127 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as COSV57148566; called by muse, mutect2, varscan2
- HTR3E | c.326del p.G109Afs*5 (on ENST00000415389 / NM_001256613.1; = p.G124Afs*5 on NM_182589.2) | Frame Shift Del (DEL) | VAF 98/677 reads (14%) | catalogued as COSV58947375; called by mutect2, pindel, varscan2
- KCNK5 | c.465G>T p.L155= | Splice Region (SNP) | VAF 30/107 reads (28%) | catalogued as COSV100851756; called by muse, mutect2, varscan2
- KLHDC4 | c.1553C>T p.A518V | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.036); catalogued as rs773015431, COSV54505995; called by muse, mutect2, varscan2
- KLHL1 | c.1975G>T p.A659S | Missense Mutation (SNP) | VAF 54/197 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.377); catalogued as COSV64777716; called by muse, mutect2, varscan2
- KLRC1 | c.238T>C p.C80R | Missense Mutation (SNP) | VAF 81/226 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs750018164, CM036119; called by muse, mutect2, varscan2
- KRT38 | c.368G>T p.R123L | Missense Mutation (SNP) | VAF 208/494 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as COSV55846793; called by muse, mutect2, varscan2
- LCE3A | c.166A>G p.R56G | Missense Mutation (SNP) | VAF 167/431 reads (39%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as rs779683963; called by muse, mutect2, varscan2
- LRRC37A2 | c.4871G>A p.R1624K | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0.055); catalogued as COSV60236185; called by mutect2, varscan2
- MMP10 | c.223A>G p.T75A | Missense Mutation (SNP) | VAF 165/202 reads (82%) | SIFT deleterious (0.01); PolyPhen benign (0.423); catalogued as rs1445033545; called by muse, mutect2, varscan2
- MMUT | c.1106G>T p.R369L | Missense Mutation (SNP) | VAF 56/228 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as CM990882, COSV51272456, COSV51275106, COSV51281714; called by muse, mutect2, varscan2
- MYH8 | c.3666G>T p.K1222N | Missense Mutation (SNP) | VAF 156/367 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67965850; called by muse, mutect2, varscan2
- MYO7A | c.1369G>A p.A457T | Missense Mutation (SNP) | VAF 155/223 reads (70%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.555); catalogued as rs782255256, COSV68687032; called by muse, mutect2, varscan2
- NCAM1 | c.893C>A p.A298E | Missense Mutation (SNP) | VAF 52/69 reads (75%) | SIFT tolerated (0.83); PolyPhen benign (0.092); catalogued as COSV57520104; called by muse, mutect2, varscan2
- NT5C1B | c.441C>A p.L147= (on ENST00000359846 / NM_001199086.2; = p.L87= on NM_033253.4) | Splice Region (SNP) | VAF 19/78 reads (24%) | catalogued as COSV58397178; called by muse, mutect2, varscan2
- NYAP2 | c.1672T>A p.L558M | Missense Mutation (SNP) | VAF 158/197 reads (80%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.9); catalogued as COSV56000401; called by muse, mutect2, varscan2
- OCA2 | c.920C>A p.S307Y | Missense Mutation (SNP) | VAF 189/237 reads (80%) | SIFT tolerated (0.32); PolyPhen benign (0.169); catalogued as COSV62357497; called by muse, mutect2, varscan2
- OR2L5 | c.123C>G p.N41K | Missense Mutation (SNP) | VAF 126/363 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.251); catalogued as rs778111135; called by muse, mutect2, varscan2
- OR5D18 | c.404T>C p.V135A | Missense Mutation (SNP) | VAF 116/181 reads (64%) | SIFT tolerated (0.06); PolyPhen benign (0.082); catalogued as rs752230763; called by muse, mutect2, varscan2
- OSBPL11 | c.1718G>T p.R573L | Missense Mutation (SNP) | VAF 48/200 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99954406; called by muse, mutect2, varscan2
- PDILT | c.648C>A p.H216Q | Missense Mutation (SNP) | VAF 37/127 reads (29%) | SIFT tolerated (0.35); PolyPhen benign (0.058); catalogued as COSV99043641; called by muse, mutect2, varscan2
- PLXNA4 | c.1096C>T p.R366C | Missense Mutation (SNP) | VAF 63/212 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs748520326, COSV58127627; called by muse, mutect2, varscan2
- RBFOX1 | c.280G>A p.D94N | Missense Mutation (SNP) | VAF 85/148 reads (57%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.412); catalogued as COSV60983816; called by muse, mutect2, varscan2
- RGS6 | c.1033G>A p.V345M | Missense Mutation (SNP) | VAF 58/238 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.197); catalogued as COSV59592981; called by muse, varscan2
- RIPK3 | c.1549G>T p.G517W | Missense Mutation (SNP) | VAF 43/160 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.92); catalogued as COSV53478475; called by muse, mutect2, varscan2
- RYR2 | c.1666G>A p.D556N | Missense Mutation (SNP) | VAF 74/189 reads (39%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.877); catalogued as rs1469603562; called by muse, mutect2, varscan2
- SACS | c.10975G>A p.A3659T | Missense Mutation (SNP) | VAF 230/284 reads (81%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as COSV66544408; called by muse, mutect2, varscan2
- SEZ6L | c.1289T>C p.M430T | Missense Mutation (SNP) | VAF 35/58 reads (60%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs778959669; called by muse, mutect2, varscan2
- SIGLECL1 | c.368G>C p.G123A | Missense Mutation (SNP) | VAF 134/179 reads (75%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV57064555; called by muse, mutect2, varscan2
- SLCO1C1 | c.1185C>T p.I395= | Splice Region (SNP) | VAF 87/284 reads (31%) | catalogued as rs766093648, COSV56868647; called by muse, mutect2, varscan2
- SP5 | c.407C>T p.A136V | Missense Mutation (SNP) | VAF 142/312 reads (46%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.448); catalogued as rs577104838; called by muse, mutect2, varscan2
- SPTA1 | c.6949C>A p.P2317T | Missense Mutation (SNP) | VAF 196/439 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1291236947; called by muse, mutect2, varscan2
- SSC5D | c.1006C>T p.R336* | Nonsense Mutation (SNP) | VAF 50/68 reads (74%) | catalogued as rs1046872451, COSV67476549; called by muse, mutect2, varscan2
- ST6GALNAC3 | c.323A>G p.N108S | Missense Mutation (SNP) | VAF 75/197 reads (38%) | PolyPhen probably damaging (1); catalogued as rs764952049; called by muse, mutect2, varscan2
- SYNE1 | c.25085C>T p.T8362M (on ENST00000367255 / NM_182961.4; = p.T8314M on NM_033071.3) | Missense Mutation (SNP) | VAF 91/283 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.964); catalogued as rs147814237; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- THADA | c.137C>T p.T46M | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.475); catalogued as rs948577418; called by muse, mutect2
- THSD7B | c.1953G>T p.E651D | Missense Mutation (SNP) | VAF 193/394 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.149); catalogued as COSV99757589; called by muse, mutect2, varscan2
- TMEM30B | c.517T>A p.S173T | Missense Mutation (SNP) | VAF 296/465 reads (64%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1010097892; called by muse, mutect2, varscan2
- TRMT61B | c.22G>T p.G8C | Missense Mutation (SNP) | VAF 46/94 reads (49%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.009); catalogued as rs771046013; called by muse, mutect2, varscan2
- USH2A | c.11978del p.G3993Afs*29 | Frame Shift Del (DEL) | VAF 152/416 reads (37%) | catalogued as COSV56335792; called by mutect2, pindel, varscan2
- XIRP2 | c.505G>A p.V169I (on ENST00000628543; = p.V344I on NM_152381.6) | Missense Mutation (SNP) | VAF 44/227 reads (19%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.763); catalogued as COSV54684760; called by muse, mutect2, varscan2
- ZNF254 | c.113A>G p.Y38C | Missense Mutation (SNP) | VAF 115/150 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1215071677; called by muse, mutect2, varscan2
- ZNF746 | c.1561C>T p.R521C | Missense Mutation (SNP) | VAF 37/117 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.149); catalogued as COSV100502621; called by muse, mutect2, varscan2
- ZNF835 | c.1463C>T p.A488V | Missense Mutation (SNP) | VAF 207/249 reads (83%) | SIFT tolerated (0.37); PolyPhen benign (0.01); catalogued as rs915967063, COSV73379200; called by muse, mutect2, varscan2
- ZP4 | c.1200C>G p.I400M | Missense Mutation (SNP) | VAF 104/222 reads (47%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.985); catalogued as COSV63910660; called by muse, mutect2, varscan2
- ABCC9 | c.307C>T p.H103Y | Missense Mutation (SNP) | VAF 284/530 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); called by muse, mutect2, varscan2
- ABHD15 | c.139G>T p.G47W | Missense Mutation (SNP) | VAF 122/277 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.277); called by muse, mutect2, varscan2
- AC055839.2 | c.278A>G p.H93R | Missense Mutation (SNP) | VAF 149/352 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.503); called by muse, mutect2, varscan2
- ADAM29 | c.1109G>C p.S370T | Missense Mutation (SNP) | VAF 46/53 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- AFF2 | c.3570G>C p.K1190N | Missense Mutation (SNP) | VAF 34/42 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AHR | c.2251G>T p.G751* | Nonsense Mutation (SNP) | VAF 116/219 reads (53%) | called by muse, mutect2, varscan2
- AKAP9 | c.10892A>G p.N3631S (on ENST00000359028; = p.N3607S on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 87/478 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- ALDH3A1 | c.559A>T p.T187S | Missense Mutation (SNP) | VAF 130/634 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AMPH | c.1739A>T p.E580V | Missense Mutation (SNP) | VAF 76/119 reads (64%) | SIFT deleterious (0.04); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ANK2 | c.3419G>T p.C1140F | Missense Mutation (SNP) | VAF 259/301 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANKRD61 | c.918T>G p.I306M | Missense Mutation (SNP) | VAF 31/116 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- ANXA11 | c.808A>T p.M270L | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT tolerated (0.43); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ASGR2 | c.56C>A p.P19H | Missense Mutation (SNP) | VAF 132/316 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- ATP6V1B1 | c.1487dup p.F497Vfs*14 | Frame Shift Ins (INS) | VAF 201/526 reads (38%) | called by mutect2, pindel, varscan2
- BFSP2 | c.289C>A p.P97T | Missense Mutation (SNP) | VAF 180/313 reads (58%) | SIFT tolerated (0.08); PolyPhen benign (0.396); called by muse, mutect2, varscan2
- CA2 | c.202G>A p.V68M | Missense Mutation (SNP) | VAF 76/458 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.801); called by muse, mutect2, varscan2
- CACNA1F | c.3830G>C p.G1277A | Missense Mutation (SNP) | VAF 55/76 reads (72%) | SIFT tolerated (0.31); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- CADM2 | c.181C>G p.Q61E (on ENST00000407528 / NM_001167674.2; = p.Q63E on NM_153184.4) | Missense Mutation (SNP) | VAF 41/102 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.281); called by muse, mutect2, varscan2
- CADPS2 | c.3419A>T p.K1140M | Missense Mutation (SNP) | VAF 133/218 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, varscan2
- CC2D1A | c.1697C>A p.P566Q | Missense Mutation (SNP) | VAF 102/117 reads (87%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.599); called by muse, mutect2, varscan2
- CD3E | c.347C>T p.A116V | Missense Mutation (SNP) | VAF 98/267 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.706); called by muse, mutect2, varscan2
- CDK18 | c.318del p.H107Tfs*69 | Frame Shift Del (DEL) | VAF 37/91 reads (41%) | called by mutect2, pindel, varscan2
- CHL1 | c.3014T>G p.I1005S (on ENST00000397491 / NM_001253387.1; = p.I1021S on NM_006614.4) | Missense Mutation (SNP) | VAF 65/76 reads (86%) | SIFT deleterious (0.01); PolyPhen benign (0.356); called by muse, mutect2, varscan2
- CNGB3 | c.259G>C p.D87H | Missense Mutation (SNP) | VAF 264/549 reads (48%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.688); called by muse, mutect2, varscan2
- COL11A1 | c.3793C>A p.P1265T | Missense Mutation (SNP) | VAF 117/151 reads (77%) | SIFT tolerated (0.11); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- COL22A1 | c.4070G>C p.G1357A | Missense Mutation (SNP) | VAF 78/273 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL6A6 | c.4159T>C p.F1387L | Missense Mutation (SNP) | VAF 121/229 reads (53%) | SIFT tolerated (0.18); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CPED1 | c.922C>T p.Q308* | Nonsense Mutation (SNP) | VAF 69/144 reads (48%) | called by muse, mutect2, varscan2
- CPNE4 | c.352C>A p.L118I | Missense Mutation (SNP) | VAF 49/99 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.578); called by muse, mutect2, varscan2
- CSTF2T | c.1702C>T p.Q568* | Nonsense Mutation (SNP) | VAF 166/284 reads (58%) | called by muse, mutect2, varscan2
- CUBN | c.9535T>C p.Y3179H | Missense Mutation (SNP) | VAF 184/249 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CUZD1 | c.1241_1242del p.Y414Lfs*13 | Frame Shift Del (DEL) | VAF 34/125 reads (27%) | called by pindel, varscan2
- CYP4V2 | c.931G>T p.G311W | Missense Mutation (SNP) | VAF 153/197 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DAAM2 | c.1220A>G p.Q407R | Missense Mutation (SNP) | VAF 50/178 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- DCAF8L2 | c.464G>T p.G155V | Missense Mutation (SNP) | VAF 28/38 reads (74%) | SIFT tolerated (0.51); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- DEFA5 | c.197A>T p.Y66F | Missense Mutation (SNP) | VAF 72/102 reads (71%) | SIFT tolerated (0.32); PolyPhen benign (0.257); called by muse, mutect2, varscan2
- DENND11 | c.609del p.G204Afs*23 | Frame Shift Del (DEL) | VAF 87/179 reads (49%) | called by mutect2, pindel, varscan2
- DIS3L2 | c.1318G>T p.V440L | Missense Mutation (SNP) | VAF 104/125 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- DNAH2 | c.7493C>T p.P2498L | Missense Mutation (SNP) | VAF 50/255 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- DUXB | c.443T>C p.M148T | Missense Mutation (SNP) | VAF 104/265 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- DYNC1H1 | c.6405+5G>T | Splice Region (SNP) | VAF 109/444 reads (25%) | called by muse, mutect2, varscan2
- EDN3 | c.160G>T p.G54C | Missense Mutation (SNP) | VAF 265/311 reads (85%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.486); called by muse, mutect2, varscan2
- EPB41L3 | c.1081A>C p.S361R | Missense Mutation (SNP) | VAF 28/221 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); called by muse, mutect2, varscan2
- EPB42 | c.1557C>A p.N519K (on ENST00000441366 / NM_001114134.2; = p.N549K on NM_000119.3) | Missense Mutation (SNP) | VAF 87/104 reads (84%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- ERICH3 | c.2132A>T p.Q711L | Missense Mutation (SNP) | VAF 82/102 reads (80%) | SIFT deleterious (0.02); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- ERO1A | c.208G>A p.E70K | Missense Mutation (SNP) | VAF 24/116 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- EYS | c.3169A>G p.T1057A | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT tolerated (0.7); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- FADS1 | c.1253A>T p.Q418L | Missense Mutation (SNP) | VAF 51/169 reads (30%) | SIFT tolerated (0.51); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- FAM135B | c.3989A>T p.K1330I | Missense Mutation (SNP) | VAF 125/312 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- FAM71D | c.239C>A p.T80N | Missense Mutation (SNP) | VAF 53/262 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- FNDC3B | c.1445G>T p.R482M | Missense Mutation (SNP) | VAF 113/175 reads (65%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.652); called by muse, mutect2, varscan2
- FOXD3 | c.241T>A p.L81M | Missense Mutation (SNP) | VAF 50/60 reads (83%) | SIFT tolerated (0.06); PolyPhen benign (0.432); called by muse, mutect2, varscan2
- FRG2C | c.643del p.R215Gfs*53 | Frame Shift Del (DEL) | VAF 68/428 reads (16%) | called by pindel, varscan2
- FRMD8 | c.499G>A p.D167N | Missense Mutation (SNP) | VAF 177/443 reads (40%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- FRMPD4 | c.2874_2880delinsG p.P959_A960del | In Frame Del (DEL) | VAF 47/58 reads (81%) | called by pindel, varscan2*
- FTO | c.734A>G p.Y245C | Missense Mutation (SNP) | VAF 74/215 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GABBR1 | c.1840A>T p.I614F | Missense Mutation (SNP) | VAF 89/140 reads (64%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- GABRR2 | c.409G>A p.D137N | Missense Mutation (SNP) | VAF 97/363 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- GALNT13 | c.1270C>A p.P424T | Missense Mutation (SNP) | VAF 76/162 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- GNGT2 | c.56A>C p.K19T | Missense Mutation (SNP) | VAF 105/299 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2
- GOLGA6D | c.586del p.V196Sfs*10 | Frame Shift Del (DEL) | VAF 187/354 reads (53%) | called by mutect2, pindel, varscan2
- GPR158 | c.2816A>T p.K939I | Missense Mutation (SNP) | VAF 133/158 reads (84%) | SIFT deleterious (0.02); PolyPhen benign (0.095); called by muse, mutect2, varscan2
- GPX6 | c.571G>T p.D191Y | Missense Mutation (SNP) | VAF 171/302 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- GRIK3 | c.973T>A p.L325I | Missense Mutation (SNP) | VAF 46/55 reads (84%) | SIFT deleterious (0); PolyPhen possibly damaging (0.674); called by muse, mutect2, varscan2
- GRIN2B | c.2303A>G p.K768R | Missense Mutation (SNP) | VAF 28/170 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- HPSE | c.194T>A p.L65Q | Missense Mutation (SNP) | VAF 102/116 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IFFO2 | c.357del p.G120Afs*93 | Frame Shift Del (DEL) | VAF 37/60 reads (62%) | called by mutect2, pindel, varscan2
- IGHV2-26 | c.123C>A p.C41* | Nonsense Mutation (SNP) | VAF 79/321 reads (25%) | called by muse, mutect2, varscan2
- IGHV3-15 | c.346T>A p.Y116N | Missense Mutation (SNP) | VAF 135/209 reads (65%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IL1RAPL1 | c.1783G>C p.A595P | Missense Mutation (SNP) | VAF 54/68 reads (79%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.68); called by muse, mutect2, varscan2
- KALRN | c.3325del p.L1109Cfs*13 | Frame Shift Del (DEL) | VAF 29/97 reads (30%) | called by mutect2, pindel, varscan2
- KCNB2 | c.2197A>T p.T733S | Missense Mutation (SNP) | VAF 181/359 reads (50%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- KIAA2026 | c.2064A>T p.K688N | Missense Mutation (SNP) | VAF 66/103 reads (64%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KLHL4 | c.2135T>C p.V712A | Missense Mutation (SNP) | VAF 78/84 reads (93%) | SIFT deleterious (0.04); PolyPhen benign (0.39); called by muse, mutect2, varscan2
- LCP1 | c.871A>G p.T291A | Missense Mutation (SNP) | VAF 101/116 reads (87%) | SIFT tolerated (0.24); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- LOXL1 | c.173del p.G58Afs*369 | Frame Shift Del (DEL) | VAF 66/106 reads (62%) | called by mutect2, pindel, varscan2
- LRRC19 | c.313T>G p.C105G | Missense Mutation (SNP) | VAF 52/75 reads (69%) | SIFT tolerated (0.51); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- MAGEB1 | c.374T>C p.M125T | Missense Mutation (SNP) | VAF 58/73 reads (79%) | SIFT tolerated (0.09); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- MED14 | c.2695A>G p.T899A | Missense Mutation (SNP) | VAF 86/101 reads (85%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- MMP16 | c.1594T>A p.C532S | Missense Mutation (SNP) | VAF 73/297 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MRC1 | c.3259T>A p.L1087M | Missense Mutation (SNP) | VAF 213/262 reads (81%) | SIFT deleterious (0.02); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- MUC5B | c.885del p.T296Pfs*176 | Frame Shift Del (DEL) | VAF 34/99 reads (34%) | called by mutect2, pindel, varscan2
- MUC5B | c.2178C>G p.F726L | Missense Mutation (SNP) | VAF 75/178 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MYH9 | c.1876G>T p.G626C | Missense Mutation (SNP) | VAF 88/321 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- MYO15A | c.2636C>G p.P879R | Missense Mutation (SNP) | VAF 154/344 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MYO9B | c.5935-3G>A | Splice Region (SNP) | VAF 35/40 reads (88%) | called by muse, mutect2, varscan2
- MYOM2 | c.1237C>A p.P413T | Missense Mutation (SNP) | VAF 43/56 reads (77%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.783); called by muse, mutect2, varscan2
- NAV1 | c.59_70dup p.G20_G23dup | In Frame Ins (INS) | VAF 37/130 reads (28%) | called by mutect2, varscan2
- NBEAL2 | c.6344A>T p.N2115I | Missense Mutation (SNP) | VAF 169/205 reads (82%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- NEU3 | c.184C>A p.L62M | Missense Mutation (SNP) | VAF 70/210 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NFXL1 | c.1053A>C p.E351D | Missense Mutation (SNP) | VAF 101/127 reads (80%) | SIFT tolerated (0.13); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- NLRC5 | c.2116C>G p.L706V | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- NLRP5 | c.1470C>A p.S490R | Missense Mutation (SNP) | VAF 172/207 reads (83%) | SIFT tolerated (0.49); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- NOS1 | c.2470G>T p.E824* | Nonsense Mutation (SNP) | VAF 33/95 reads (35%) | called by muse, mutect2, varscan2
- NOX5 | c.1099G>T p.A367S | Missense Mutation (SNP) | VAF 74/159 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NPY1R | c.916C>T p.H306Y | Missense Mutation (SNP) | VAF 46/128 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); called by muse, varscan2
- NRK | c.3181G>T p.G1061* | Nonsense Mutation (SNP) | VAF 174/196 reads (89%) | called by muse, mutect2, varscan2
- OR11A1 | c.81C>A p.F27L | Missense Mutation (SNP) | VAF 43/161 reads (27%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR2F1 | c.506G>A p.C169Y | Missense Mutation (SNP) | VAF 53/218 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- OR52E4 | c.742G>A p.V248I | Missense Mutation (SNP) | VAF 55/113 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.434); called by muse, mutect2, varscan2
- OR5H6 | c.334G>C p.E112Q (on ENST00000642105; = p.E96Q on NM_001005479.2) | Missense Mutation (SNP) | VAF 96/190 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- OR8I2 | c.187C>A p.L63M | Missense Mutation (SNP) | VAF 51/86 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- OTOP1 | c.1640C>A p.A547E | Missense Mutation (SNP) | VAF 62/75 reads (83%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- OTX2 | c.701C>T p.S234F (on ENST00000408990 / NM_172337.3; = p.S242F on NM_021728.4) | Missense Mutation (SNP) | VAF 105/461 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- PAM | c.1504C>G p.L502V | Missense Mutation (SNP) | VAF 36/42 reads (86%) | SIFT tolerated (0.84); PolyPhen benign (0); called by muse, mutect2, varscan2
- PCDH12 | c.2416G>T p.A806S | Missense Mutation (SNP) | VAF 172/213 reads (81%) | SIFT tolerated (0.69); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PCDH15 | c.5023G>C p.E1675Q | Missense Mutation (SNP) | VAF 96/236 reads (41%) | SIFT deleterious, low confidence (0.02); called by muse, varscan2
- PCDH15 | c.5013del p.M1672Wfs*148 | Frame Shift Del (DEL) | VAF 94/280 reads (34%) | called by pindel, varscan2
- PDE4A | c.662C>T p.T221M | Missense Mutation (SNP) | VAF 50/63 reads (79%) | SIFT tolerated (0.06); PolyPhen benign (0.195); called by muse, mutect2, varscan2
- PHF8 | c.347T>A p.V116E (on ENST00000357988 / NM_001184896.1; = p.V80E on NM_015107.3) | Missense Mutation (SNP) | VAF 129/162 reads (80%) | SIFT deleterious (0); PolyPhen possibly damaging (0.524); called by muse, mutect2, varscan2
- POC1B | c.566C>T p.A189V | Missense Mutation (SNP) | VAF 55/80 reads (69%) | SIFT tolerated (0.64); PolyPhen benign (0.401); called by muse, mutect2, varscan2
- POM121L2 | c.2128G>T p.V710L | Missense Mutation (SNP) | VAF 153/282 reads (54%) | SIFT deleterious (0.04); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- PON3 | c.109G>T p.V37L | Missense Mutation (SNP) | VAF 95/419 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- PPP1R9A | c.1649G>T p.R550I | Missense Mutation (SNP) | VAF 89/125 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- PRICKLE4 | c.128A>G p.Y43C (on ENST00000359201; = p.Y83C on NM_013397.6) | Missense Mutation (SNP) | VAF 83/153 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RALGPS2 | c.826G>T p.D276Y | Missense Mutation (SNP) | VAF 82/221 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- RANGAP1 | c.242G>C p.R81P | Missense Mutation (SNP) | VAF 90/182 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.663); called by muse, mutect2, varscan2
- RP1 | c.1837A>G p.T613A | Missense Mutation (SNP) | VAF 106/880 reads (12%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- SAFB2 | c.2378A>G p.D793G | Missense Mutation (SNP) | VAF 55/174 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.539); called by muse, mutect2, varscan2
- SAMSN1 | c.595G>T p.D199Y | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); called by muse, varscan2
- SCMH1 | c.1030C>A p.Q344K (on ENST00000326197 / NM_001031694.2; = p.Q297K on NM_012236.4) | Missense Mutation (SNP) | VAF 164/194 reads (85%) | SIFT tolerated (0.67); PolyPhen benign (0.109); called by muse, varscan2
- SEL1L | c.300A>T p.E100D | Missense Mutation (SNP) | VAF 41/177 reads (23%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- SEMA6D | c.1969C>A p.Q657K (on ENST00000316364 / NM_153618.2; = p.Q595K on NM_020858.2) | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.876); called by muse, mutect2
- SERPINB3 | c.1045G>A p.V349I | Missense Mutation (SNP) | VAF 105/141 reads (74%) | SIFT tolerated (0.46); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SH2D7 | c.646-1G>A p.X216_splice | Splice Site (SNP) | VAF 25/82 reads (30%) | called by muse, mutect2, varscan2
- SLC27A6 | c.1241T>C p.I414T | Missense Mutation (SNP) | VAF 83/102 reads (81%) | SIFT tolerated (0.19); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- SLC30A3 | c.462G>T p.W154C | Missense Mutation (SNP) | VAF 87/233 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC30A3 | c.461G>T p.W154L | Missense Mutation (SNP) | VAF 85/231 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC4A1 | c.532C>A p.L178M | Missense Mutation (SNP) | VAF 324/712 reads (46%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.746); called by muse, mutect2, varscan2
- SLC6A5 | c.1199T>A p.L400H | Missense Mutation (SNP) | VAF 119/321 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SMG8 | c.1526G>C p.S509T | Missense Mutation (SNP) | VAF 95/196 reads (48%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- SORCS1 | c.632C>A p.T211N | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.748); called by muse, mutect2, varscan2
- STX1B | c.432_457del p.C144* | Nonsense Mutation (DEL) | VAF 77/207 reads (37%) | called by mutect2, pindel, varscan2
- SV2A | c.374G>C p.G125A | Missense Mutation (SNP) | VAF 120/250 reads (48%) | SIFT tolerated (0.99); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SYT9 | c.613C>A p.Q205K | Missense Mutation (SNP) | VAF 42/132 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- TBP | c.308A>T p.Q103L | Missense Mutation (SNP) | VAF 194/514 reads (38%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- TDRD6 | c.1939G>C p.D647H | Missense Mutation (SNP) | VAF 52/99 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- THNSL2 | c.315G>T p.W105C | Missense Mutation (SNP) | VAF 131/339 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- TKFC | c.367G>A p.E123K | Missense Mutation (SNP) | VAF 35/164 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TMPRSS15 | c.1487G>T p.S496I | Missense Mutation (SNP) | VAF 312/420 reads (74%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); called by muse, mutect2
- TP53TG5 | c.522del p.R175Gfs*25 | Frame Shift Del (DEL) | VAF 209/333 reads (63%) | called by mutect2, pindel, varscan2
- TPM2 | c.563+6G>A | Splice Region (SNP) | VAF 307/565 reads (54%) | called by muse, mutect2, varscan2
- TTLL5 | c.2366A>T p.Q789L | Missense Mutation (SNP) | VAF 47/185 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- TXNDC16 | c.1218G>T p.M406I | Missense Mutation (SNP) | VAF 142/210 reads (68%) | SIFT tolerated (0.15); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- UGGT1 | c.2629G>T p.A877S | Missense Mutation (SNP) | VAF 100/219 reads (46%) | SIFT tolerated (0.34); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- USH2A | c.7942A>G p.T2648A | Missense Mutation (SNP) | VAF 140/330 reads (42%) | SIFT tolerated (0.88); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- USP38 | c.2426T>A p.V809E | Missense Mutation (SNP) | VAF 49/155 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- ZBTB7B | c.896C>A p.S299Y (on ENST00000292176; = p.S333Y on NM_001252406.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 70/151 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); called by muse, mutect2, varscan2
- ZFHX4 | c.1340G>T p.R447M | Missense Mutation (SNP) | VAF 63/276 reads (23%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- ZNF385B | c.536T>C p.L179P | Missense Mutation (SNP) | VAF 62/142 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- ZNF534 | c.973A>C p.S325R (on ENST00000332323 / NM_001143939.3; = p.S312R on NM_001143938.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 94/112 reads (84%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- ZNF835 | c.918C>A p.Y306* | Nonsense Mutation (SNP) | VAF 142/194 reads (73%) | called by muse, mutect2, varscan2
- AMOT | c.1120C>T p.L374= | Silent (SNP) | VAF 34/385 reads (9%) | called by muse, mutect2
- ANXA11 | c.807G>T p.L269= | Silent (SNP) | VAF 18/70 reads (26%) | called by muse, mutect2, varscan2
- APOB | c.2571A>G p.G857= | Silent (SNP) | VAF 130/292 reads (45%) | called by muse, mutect2, varscan2
- ASB2 | c.744C>T p.D248= | Silent (SNP) | VAF 37/164 reads (23%) | catalogued as rs1366933382; called by muse, mutect2, varscan2
- C2CD2L | c.81C>T p.F27= | Silent (SNP) | VAF 86/183 reads (47%) | called by muse, mutect2, varscan2
- C5 | c.4353T>A p.T1451= | Silent (SNP) | VAF 205/244 reads (84%) | called by muse, mutect2, varscan2
- CACNA1C | c.3975C>T p.I1325= | Silent (SNP) | VAF 47/289 reads (16%) | catalogued as rs1287061592; called by muse, mutect2, varscan2
- CASQ1 | c.1086C>T p.D362= | Silent (SNP) | VAF 161/319 reads (50%) | catalogued as rs764442615, COSV63623465; called by muse, mutect2, varscan2
- CCT8L2 | c.894G>A p.E298= | Silent (SNP) | VAF 211/497 reads (42%) | called by muse, mutect2, varscan2
- CD4 | c.543C>A p.T181= | Silent (SNP) | VAF 87/489 reads (18%) | called by muse, mutect2, varscan2
- CPSF4 | c.765C>T p.A255= | Silent (SNP) | VAF 108/461 reads (23%) | called by muse, mutect2, varscan2
- CSMD1 | c.6156G>C p.A2052= (on ENST00000520002; = p.A2051= on NM_033225.6) | Silent (SNP) | VAF 105/156 reads (67%) | called by muse, mutect2, varscan2
- DVL3 | c.174G>A p.E58= | Silent (SNP) | VAF 153/1392 reads (11%) | called by muse, mutect2, varscan2
- EPPK1 | c.6591C>T p.L2197= | Silent (SNP) | VAF 332/628 reads (53%) | catalogued as COSV73262273; called by muse, mutect2, varscan2
- FAM135B | c.3144C>A p.P1048= | Silent (SNP) | VAF 56/179 reads (31%) | called by muse, mutect2, varscan2
- FCSK | c.348C>T p.P116= | Silent (SNP) | VAF 187/289 reads (65%) | catalogued as rs545717545, COSV99850542; called by muse, mutect2, varscan2
- FSCB | c.720A>G p.V240= | Silent (SNP) | VAF 166/242 reads (69%) | called by muse, mutect2, varscan2
- FUBP3 | c.828C>A p.I276= | Silent (SNP) | VAF 58/74 reads (78%) | catalogued as COSV60513396; called by muse, mutect2, varscan2
- GGT6 | c.771G>A p.V257= (on ENST00000574154 / NM_001122890.3; = p.V225= on NM_153338.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 87/202 reads (43%) | catalogued as rs1233989966; called by muse, mutect2, varscan2
- GJA8 | c.645G>T p.V215= | Silent (SNP) | VAF 131/311 reads (42%) | called by muse, mutect2, varscan2
- GOLGA6L10 | c.933G>A p.E311= | Silent (SNP) | VAF 178/884 reads (20%) | called by muse, varscan2
- GPAT4 | c.600G>A p.L200= | Silent (SNP) | VAF 134/139 reads (96%) | called by muse, mutect2, varscan2
- GPR108 | c.462G>T p.P154= | Silent (SNP) | VAF 151/177 reads (85%) | catalogued as COSV51184632; called by muse, mutect2, varscan2
- HFM1 | c.3438T>C p.L1146= | Silent (SNP) | VAF 99/129 reads (77%) | catalogued as COSV99645921; called by muse, mutect2, varscan2
- ITGAM | c.3240C>T p.F1080= (on ENST00000648685 / NM_001145808.2; = p.F1079= on NM_000632.4) | Silent (SNP) | VAF 24/59 reads (41%) | called by muse, mutect2, varscan2
- KIAA1217 | c.2397G>A p.K799= | Silent (SNP) | VAF 63/83 reads (76%) | called by muse, mutect2, varscan2
- KIF2B | c.1878A>G p.R626= | Silent (SNP) | VAF 48/223 reads (22%) | catalogued as COSV52132063; called by muse, mutect2, varscan2
- KIF7 | c.24G>A p.L8= | Silent (SNP) | VAF 14/17 reads (82%) | catalogued as rs1313620637; called by muse, mutect2, varscan2
- LDB3 | c.1383T>C p.Y461= | Silent (SNP) | VAF 30/87 reads (34%) | called by muse, mutect2, varscan2
- MAEL | c.402C>T p.F134= | Silent (SNP) | VAF 83/219 reads (38%) | called by muse, mutect2, varscan2
- MYH7B | c.477C>A p.G159= | Silent (SNP) | VAF 29/88 reads (33%) | called by muse, mutect2, varscan2
- MYOCD | c.264A>G p.A88= | Silent (SNP) | VAF 48/101 reads (48%) | catalogued as rs780955626; called by muse, mutect2, varscan2
- NTRK3 | c.2244T>C p.T748= (on ENST00000360948 / NM_001012338.2; = p.T734= on NM_002530.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 75/192 reads (39%) | called by muse, mutect2, varscan2
- NUAK1 | c.1185G>A p.K395= | Silent (SNP) | VAF 161/273 reads (59%) | catalogued as COSV54602871; called by muse, mutect2, varscan2
- NUCKS1 | c.159T>C p.N53= | Silent (SNP) | VAF 201/423 reads (48%) | called by muse, mutect2, varscan2
- PPP1R2B | c.291A>G p.P97= | Silent (SNP) | VAF 226/296 reads (76%) | catalogued as rs1401651272; called by muse, mutect2, varscan2
- RAPGEFL1 | c.1971G>T p.L657= | Silent (SNP) | VAF 115/248 reads (46%) | called by muse, mutect2, varscan2
- RFX3 | c.1797A>G p.L599= | Silent (SNP) | VAF 54/81 reads (67%) | catalogued as rs763984737; called by mutect2, varscan2
- RIMS4 | c.6G>A p.E2= | Silent (SNP) | VAF 32/78 reads (41%) | called by muse, mutect2, varscan2
- RSPH3 | c.1353G>A p.V451= (on ENST00000252655; = p.V309= on NM_031924.8) | Silent (SNP) | VAF 50/136 reads (37%) | catalogued as rs752489731; called by muse, mutect2, varscan2
- RUNX1T1 | c.942C>T p.S314= (on ENST00000265814 / NM_001198628.1; = p.S287= on NM_004349.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 128/230 reads (56%) | called by muse, mutect2, varscan2
- SH3BP4 | c.2646G>A p.R882= | Silent (SNP) | VAF 54/64 reads (84%) | catalogued as COSV99060197; called by muse, mutect2, varscan2
- SLC22A10 | c.876A>G p.L292= | Silent (SNP) | VAF 126/162 reads (78%) | called by muse, mutect2, varscan2
- SLC39A12 | c.1671A>G p.L557= (on ENST00000377369 / NM_001145195.2; = p.L520= on NM_152725.3) | Silent (SNP) | VAF 133/167 reads (80%) | called by muse, mutect2, varscan2
- SLC7A5 | c.243G>T p.S81= | Silent (SNP) | VAF 155/353 reads (44%) | catalogued as COSV55363972; called by muse, mutect2, varscan2
- SLCO4C1 | c.1932T>G p.L644= | Silent (SNP) | VAF 22/81 reads (27%) | called by muse, mutect2, varscan2
- SORCS1 | c.2640C>A p.A880= | Silent (SNP) | VAF 31/70 reads (44%) | called by muse, mutect2, varscan2
- TDRD9 | c.2071C>A p.R691= | Silent (SNP) | VAF 77/137 reads (56%) | catalogued as COSV59156031; called by muse, mutect2, varscan2
- TFAP2B | c.1248C>A p.A416= | Silent (SNP) | VAF 164/322 reads (51%) | called by muse, varscan2
- TMEM132B | c.2637G>A p.P879= | Silent (SNP) | VAF 66/220 reads (30%) | catalogued as rs191297957; called by muse, mutect2, varscan2
- TMPRSS15 | c.2940C>T p.N980= | Silent (SNP) | VAF 581/771 reads (75%) | called by muse, mutect2, varscan2
- TMPRSS6 | c.180G>T p.G60= | Silent (SNP) | VAF 305/507 reads (60%) | catalogued as rs773477033, COSV60975687; called by muse, mutect2, varscan2
- TPM2 | c.435G>A p.E145= | Silent (SNP) | VAF 367/677 reads (54%) | called by muse, mutect2, varscan2
- TYMS | c.723G>T p.T241= | Silent (SNP) | VAF 28/205 reads (14%) | called by muse, mutect2, varscan2
- UNG | c.237C>A p.A79= (on ENST00000242576 / NM_080911.3; = p.A70= on NM_003362.4) | Silent (SNP) | VAF 25/108 reads (23%) | called by muse, mutect2, varscan2
- VLDLR | c.570G>A p.P190= | Silent (SNP) | VAF 29/40 reads (73%) | catalogued as rs116556362; called by muse, mutect2, varscan2
- ZNF358 | c.186A>G p.E62= | Silent (SNP) | VAF 135/165 reads (82%) | called by muse, mutect2, varscan2
- ZNF438 | c.420C>A p.I140= | Silent (SNP) | VAF 119/146 reads (82%) | called by muse, mutect2, varscan2
- ZNF45 | c.102A>T p.R34= | Silent (SNP) | VAF 82/100 reads (82%) | called by muse, mutect2, varscan2
- ZNF780B | c.2379C>T p.H793= | Silent (SNP) | VAF 104/130 reads (80%) | catalogued as rs1263791928; called by muse, mutect2, varscan2
- ZNF804B | c.3987T>C p.S1329= | Silent (SNP) | VAF 41/177 reads (23%) | called by muse, mutect2, varscan2
- ZSCAN29 | c.498G>A p.E166= | Silent (SNP) | VAF 52/60 reads (87%) | called by muse, mutect2, varscan2
- AC093582.1 | n.245C>G | RNA (SNP) | VAF 238/345 reads (69%) | called by muse, mutect2, varscan2
- ANKFN1 | chr17:56153472 G>T | 5'Flank (SNP) | VAF 47/254 reads (19%) | catalogued as rs762434757; called by muse, mutect2, varscan2
- APOOP5 | n.383G>T | RNA (SNP) | VAF 26/63 reads (41%) | called by muse, mutect2, varscan2
- ASIC2 | c.556-179436G>T | Intron (SNP) | VAF 90/251 reads (36%) | called by muse, mutect2, varscan2
- BEST1 | c.867+146C>A | Intron (SNP) | VAF 77/251 reads (31%) | catalogued as COSV57120592; called by muse, mutect2, varscan2
- BTN2A3P | n.1448-192T>C | Intron (SNP) | VAF 149/270 reads (55%) | catalogued as rs376674422; called by muse, mutect2, varscan2
- CAPN15 | c.*1042G>A | 3'UTR (SNP) | VAF 76/305 reads (25%) | catalogued as rs1453272488, COSV54834840; called by muse, mutect2, varscan2
- CCDC60 | c.170+4785C>A | Intron (SNP) | VAF 150/275 reads (55%) | catalogued as COSV59541812; called by muse, mutect2, varscan2
- CHMP4A | c.-46A>C | 5'UTR (SNP) | VAF 74/319 reads (23%) | called by muse, mutect2, varscan2
- COL28A1 | c.883-679C>A | Intron (SNP) | VAF 32/96 reads (33%) | called by muse, mutect2, varscan2
- CRB1 | c.1172-7069C>A | Intron (SNP) | VAF 61/178 reads (34%) | catalogued as rs1285312912; called by muse, mutect2, varscan2
- DBF4B | c.1189+720G>C | Intron (SNP) | VAF 160/328 reads (49%) | called by muse, mutect2, varscan2
- DHX33 | c.-90G>C | 5'UTR (SNP) | VAF 75/147 reads (51%) | called by muse, mutect2, varscan2
- EIF2B1 | c.-26dup | 5'UTR (INS) | VAF 93/352 reads (26%) | called by mutect2, pindel, varscan2
- EYS | c.1767-7998C>T | Intron (SNP) | VAF 19/106 reads (18%) | called by mutect2, varscan2
- FMN2 | c.5061-50A>T | Intron (SNP) | VAF 63/162 reads (39%) | called by muse, mutect2, varscan2
- FMN2 | c.5061-49G>A | Intron (SNP) | VAF 64/161 reads (40%) | called by muse, mutect2, varscan2
- FOLH1B | n.1016G>T | RNA (SNP) | VAF 84/104 reads (81%) | called by muse, varscan2
- FOXF1 | c.-29G>A | 5'UTR (SNP) | VAF 14/45 reads (31%) | catalogued as rs779233044; called by muse, mutect2, varscan2
- GABRA6 | c.529+12C>T | Intron (SNP) | VAF 70/176 reads (40%) | called by muse, mutect2, varscan2
- GCNT2 | c.925+27022C>T | Intron (SNP) | VAF 59/240 reads (25%) | called by muse, mutect2, varscan2
- HOOK3 | c.1620+27G>C | Intron (SNP) | VAF 351/372 reads (94%) | called by muse, mutect2, varscan2
- IGFN1 | c.1241+744del | Intron (DEL) | VAF 73/167 reads (44%) | catalogued as COSV55180562; called by mutect2, pindel, varscan2
- IGKV2D-26 | c.-4C>T | 5'UTR (SNP) | VAF 63/302 reads (21%) | catalogued as rs1452439313; called by muse, varscan2
- KDM2A | c.*538G>C | 3'UTR (SNP) | VAF 95/185 reads (51%) | called by muse, mutect2, varscan2
- MYRF | c.46+4437G>T | Intron (SNP) | VAF 90/289 reads (31%) | catalogued as rs1436805799; called by muse, mutect2, varscan2
- NEBL | c.2346+25A>G | Intron (SNP) | VAF 52/132 reads (39%) | catalogued as rs1231901437; called by muse, mutect2, varscan2
- NHLRC2 | c.*6418C>T | 3'UTR (SNP) | VAF 44/108 reads (41%) | called by muse, varscan2
- NRXN1 | c.3719-1433T>A | Intron (SNP) | VAF 105/266 reads (39%) | called by muse, mutect2, varscan2
- OR6Y1 | chr1:158548106 G>T | 5'Flank (SNP) | VAF 32/78 reads (41%) | called by muse, mutect2, varscan2
- OR8H1 | c.*24A>T | 3'UTR (SNP) | VAF 69/114 reads (61%) | catalogued as rs778412172; called by muse, mutect2, varscan2
- PDZD7 | chr10:101015694 A>T | 3'Flank (SNP) | VAF 50/156 reads (32%) | called by muse, mutect2, varscan2
- PKD1L1 | c.7174-253C>G | Intron (SNP) | VAF 84/139 reads (60%) | called by muse, mutect2, varscan2
- PTPRR | c.1498-10339C>A | Intron (SNP) | VAF 46/143 reads (32%) | called by muse, mutect2, varscan2
- SLC25A51P4 | n.673C>A | RNA (SNP) | VAF 73/178 reads (41%) | called by muse, mutect2, varscan2
- STON1-GTF2A1L | c.*46A>T | 3'UTR (SNP) | VAF 103/218 reads (47%) | catalogued as rs775167119; called by muse, mutect2, varscan2
- VSTM2L | c.-25G>A | 5'UTR (SNP) | VAF 36/48 reads (75%) | catalogued as rs574594514; called by muse, mutect2
- ZBBX | c.2138-9488C>A | Intron (SNP) | VAF 22/97 reads (23%) | called by muse, mutect2, varscan2
